Gene-level copy-number profile of tumor specimen TCGA-13-1483-01A from TCGA case TCGA-13-1483, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 61.2 years (22,342 days).
Specimen TCGA-13-1483-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.47e05fb0-cbc1-4edd-a8d6-ae4a20ceb7c2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-1483-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/eb61e7bc-3c69-4620-8b86-b3300a1cf241

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 16,982; copy number 2: 31,837; copy number 3: 9,103; copy number 4: 1,533; copy number 5: 5; copy number 6: 359.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-1483-01A-01D-0472-01): tumor purity 0.77, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 364 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:196,946,356–197,029,817, 5 genes, copy number 5 (within-gene range 2–5): PIGZ, AC011322.1, RPSAP69, MELTF, MELTF-AS1.
- chr8:125,859,721–145,066,685, 359 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 16,982. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
